Gene-level copy-number profile of tumor specimen TCGA-EB-A41B-01A from TCGA case TCGA-EB-A41B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 76.7 years (27,998 days).
Specimen TCGA-EB-A41B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6cfcd132-a1a2-4431-ab1c-45dcae966823.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A41B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/243f7d3a-23f2-4cee-9a8b-6951ae743005

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 12,554; copy number 2: 42,508; copy number 3: 2,914; copy number 4: 1,242; copy number 5: 204; copy number 6: 343; copy number 7: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A41B-01A-11D-A24Q-01): tumor purity 0.88, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:138,063,268–138,497,261, 2 genes (within-gene range 0–1): AC079015.1, FAM135B.
- chr9:16,409,503–16,870,843, 1 gene (within-gene range 0–1): BNC2.
- chr9:16,625,676–16,775,845, 3 genes: AL450003.1, BNC2-AS1, LSM1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 588 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:12,199,130–12,199,201, 1 gene, copy number 6: MIR3681.
- chr2:12,598,987–12,605,145, 1 gene, copy number 6: AC096559.1.
- chr11:57,703,714–58,442,758, 41 genes, copy number 7: MED19, AP001931.2, TMX2, PPIAP42, SELENOH, AP001931.1, BTBD18, CTNND1, OR5BA1P, AP003484.1, OR5AZ1P, OR5BD1P, CYCSP26, OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12.
- chr11:66,330,241–86,714,092, 545 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
